Somatic mutation profile of tumor specimen TCGA-AX-A2H7-01A (aliquot TCGA-AX-A2H7-01A-12D-A18P-09) from TCGA case TCGA-AX-A2H7, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IC; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-AX-A2H7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39236e83-5fed-4469-86da-edb778462bef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A2H7-10A (Blood Derived Normal), aliquot TCGA-AX-A2H7-10A-01D-A18P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/482e8bf9-137a-4748-a1f1-9e8cbe8c34e2

The open-access MAF lists 95 somatic variants for this specimen: 72 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 21, Nonsense Mutation 5, Frame Shift Del 5, Frame Shift Ins 1, Intron 1, Splice Site 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 53/128 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50461395, COSV50462411; called by muse, mutect2, varscan2
- ADAM2 | c.1143C>G p.F381L | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV55862386, COSV99696663; called by muse, mutect2, varscan2
- ADAM23 | c.2312G>A p.R771Q | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.125); catalogued as rs758501499, COSV100008282; called by muse, mutect2, varscan2
- ALG13 | c.3247G>C p.D1083H | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99322691; called by mutect2, varscan2
- ANKRD17 | c.5203A>G p.T1735A | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as COSV100429681; called by muse, mutect2, varscan2
- APOL3 | c.106A>G p.I36V | Missense Mutation (SNP) | VAF 16/30 reads (53%) | PolyPhen benign (0.019); catalogued as rs1569530047, COSV100652132; called by muse, mutect2, varscan2
- ASCC3 | c.2606C>T p.T869M | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs776337019, COSV100226094; called by muse, mutect2, varscan2
- ASXL3 | c.2791C>T p.Q931* | Nonsense Mutation (SNP) | VAF 3/10 reads (30%) | catalogued as COSV52463160; called by muse, mutect2
- C3 | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | catalogued as COSV99837043; called by mutect2, varscan2
- CAMTA2 | c.3331A>C p.K1111Q | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV99236707; called by muse, mutect2, varscan2
- CDH2 | c.2524G>T p.A842S | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99297742; called by muse, mutect2, varscan2
- CDH26 | c.781G>A p.V261I | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.08); catalogued as rs376455734; called by muse, mutect2, varscan2
- CNBD1 | c.523C>A p.L175M | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV101575297, COSV72976810; called by muse, mutect2, varscan2
- CTCF | c.1409del p.R470Lfs*41 | Frame Shift Del (DEL) | VAF 44/135 reads (33%) | catalogued as COSV99866624; called by mutect2, pindel, varscan2
- DDB1 | c.1945G>A p.V649I | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.777); catalogued as rs1194687578, COSV57100986; called by muse, mutect2
- DUSP11 | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 66/122 reads (54%) | catalogued as rs754705080, COSV55595147, COSV99730981; called by muse, mutect2, varscan2
- EFR3A | c.1777del p.H593Ifs*16 | Frame Shift Del (DEL) | VAF 13/93 reads (14%) | catalogued as COSV54462349; called by mutect2, pindel, varscan2
- FADD | c.35C>G p.S12W | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100096713; called by muse, mutect2
- FGD6 | c.2485G>T p.D829Y | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100676729; called by muse, mutect2, varscan2
- FILIP1 | c.2411G>T p.G804V | Missense Mutation (SNP) | VAF 42/63 reads (67%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.461); catalogued as COSV99385590; called by muse, mutect2, varscan2
- GALNT13 | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.996); catalogued as rs776718504, COSV67212711; called by muse, mutect2, varscan2
- GIGYF1 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99309739; called by muse, mutect2, varscan2
- GLI2 | c.4063C>T p.R1355W (on ENST00000361492 / NM_001374353.1; = p.R1372W on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs745816777, COSV100083908; called by muse, varscan2
- HDAC6 | c.3625G>T p.E1209* | Nonsense Mutation (SNP) | VAF 48/73 reads (66%) | catalogued as COSV57807081; called by muse, mutect2, varscan2
- HMGCS1 | c.49G>A p.V17M | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100285043; called by muse, mutect2
- HOXB6 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.75); PolyPhen benign (0.022); catalogued as rs768603811, COSV99494655; called by muse, mutect2, varscan2
- ITGA7 | c.3251T>C p.V1084A (on ENST00000555728; = p.V1040A on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV99145342; called by muse, mutect2, varscan2
- IZUMO2 | c.427del p.E143Kfs*86 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | catalogued as COSV99518151; called by mutect2, pindel, varscan2
- KCNJ2 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 14/195 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM125448, COSV99696455; called by muse, mutect2
- KCNQ5 | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59648855; called by muse, mutect2, varscan2
- LMCD1 | c.766G>A p.V256M | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as COSV99337720; called by muse, mutect2
- LPIN2 | c.308T>G p.L103R | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99858701; called by muse, mutect2
- MMP16 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54191067; called by muse, mutect2, varscan2
- MMRN1 | c.2647G>A p.G883S | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs750485732, COSV53337147; called by muse, mutect2, varscan2
- MRGPRX4 | c.329T>G p.L110R | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100049773; called by muse, mutect2, varscan2
- MROH2B | c.2839C>T p.R947C | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368897376; called by muse, mutect2, varscan2
- MS4A14 | c.1797G>T p.K599N | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.328); catalogued as COSV100280629; called by muse, mutect2, varscan2
- NIPBL | c.5575G>A p.D1859N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56950376, COSV99241857; called by muse, mutect2, varscan2
- OR2T27 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1363068542, COSV61283144; called by muse, mutect2, varscan2
- OR6F1 | c.893G>T p.R298I | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV100129349; called by muse, mutect2, varscan2
- PACS1 | c.2840C>T p.T947I | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV100270362; called by muse, mutect2, varscan2
- PBRM1 | c.3553C>T p.R1185* (on ENST00000296302 / NM_001366071.2; = p.R1160* on NM_018313.5) | Nonsense Mutation (SNP) | VAF 56/108 reads (52%) | catalogued as COSV56264314; called by muse, mutect2
- PCDHB5 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.08); catalogued as rs782266109, COSV50647266; called by muse, mutect2, varscan2
- PEG3 | c.1903A>G p.T635A | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.754); catalogued as COSV99689810; called by muse, mutect2, varscan2
- PGGHG | c.965T>G p.L322R | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101164609; called by muse, mutect2, varscan2
- PILRB | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs375039008; called by muse, mutect2, varscan2
- PLXNA3 | c.1487G>T p.S496I | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.203); catalogued as COSV100860131; called by muse, mutect2, varscan2
- PPP3CA | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1485755431, COSV100547894; called by muse, mutect2, varscan2
- PPRC1 | c.2276G>A p.R759Q | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as COSV53384700; called by muse, mutect2
- PRPF8 | c.5517G>T p.W1839C | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59268573; called by muse, mutect2, varscan2
- PSMD1 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs773462343, COSV100433768; called by muse, mutect2, varscan2
- RDH16 | c.185C>T p.T62M | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs371699976; called by muse, mutect2, varscan2
- RGS22 | c.2271C>A p.D757E | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs763009403, COSV100693585; called by muse, mutect2, varscan2
- RPL11 | c.232G>A p.A78T (on ENST00000374550 / NM_001199802.1; = p.A79T on NM_000975.5) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV100999681; called by muse, mutect2, varscan2
- SACS | c.13127C>A p.S4376Y | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.817); catalogued as COSV101207566; called by muse, mutect2, varscan2
- SALL2 | c.1939C>A p.R647S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746092722, COSV100444523, COSV58103814; called by muse, mutect2, varscan2
- SEMA4F | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143261584; called by muse, mutect2, varscan2
- SPG21 | c.797A>G p.N266S | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.301); catalogued as rs764559344, COSV99200193; called by muse, mutect2, varscan2
- THOC5 | c.370G>T p.D124Y | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100803635; called by muse, mutect2, varscan2
- TM9SF4 | c.528+2T>C p.X176_splice | Splice Site (SNP) | VAF 16/41 reads (39%) | catalogued as COSV99454939; called by muse, mutect2, varscan2
- TMPRSS2 | c.726A>C p.I242= | Splice Region (SNP) | VAF 40/113 reads (35%) | catalogued as COSV100152016; called by muse, mutect2, varscan2
- TRANK1 | c.2104G>T p.D702Y | Missense Mutation (SNP) | VAF 29/39 reads (74%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as COSV100083956, COSV57157914; called by muse, mutect2, varscan2
- TRIM21 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.79); PolyPhen benign (0.013); catalogued as rs574966130, COSV54345432; called by muse, mutect2, varscan2
- TTLL9 | c.182G>A p.R61K | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.101); catalogued as rs763601317, COSV100207059; called by muse, mutect2, varscan2
- WDR90 | c.3925G>A p.G1309R | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV53475001; called by muse, mutect2
- XRN1 | c.1871G>A p.R624Q | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs150688965; called by muse, mutect2, varscan2
- ZNF626 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.072); catalogued as COSV99391795; called by muse, mutect2, varscan2
- ZP4 | c.1339T>C p.C447R | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100850735; called by muse, mutect2, varscan2
- BZW1 | c.212_213del p.F71* | Frame Shift Del (DEL) | VAF 51/176 reads (29%) | called by mutect2, pindel, varscan2
- PIK3R4 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SIN3A | c.921del p.I308Sfs*46 | Frame Shift Del (DEL) | VAF 30/103 reads (29%) | called by mutect2, pindel, varscan2
- ZFP36L2 | c.111dup p.T38Dfs*46 | Frame Shift Ins (INS) | VAF 13/28 reads (46%) | called by mutect2, pindel, varscan2
- AZIN1 | c.387T>C p.N129= | Silent (SNP) | VAF 46/123 reads (37%) | catalogued as COSV100457687; called by muse, mutect2, varscan2
- CHIA | c.372C>T p.I124= (on ENST00000343320; = p.I16= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as rs1273983028, COSV100588764, COSV58474080; called by muse, mutect2, varscan2
- CYP11B2 | c.1218C>T p.F406= | Silent (SNP) | VAF 8/177 reads (5%) | called by muse, mutect2
- DROSHA | c.3225C>G p.R1075= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs749231991, COSV100757741, COSV60780391; called by muse, mutect2, varscan2
- FLT1 | c.1365C>T p.T455= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as rs753091980; called by muse, mutect2, varscan2
- GET1 | c.12C>G p.A4= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV100414421; called by muse, mutect2, varscan2
- HPCA | c.180C>T p.D60= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs555055449, COSV65102815; ClinVar: likely benign; called by muse, mutect2, varscan2
- JUN | c.324G>A p.E108= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV100973466; called by muse, mutect2, varscan2
- NFASC | c.2265G>A p.S755= (on ENST00000339876 / NM_001378329.1; = p.S751= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as rs544193180, COSV100364974; called by mutect2, varscan2
- NTRK2 | c.1720C>T p.L574= (on ENST00000323115 / NM_001369534.1; = p.L590= on NM_006180.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV99457396; called by muse, mutect2, varscan2
- PCYT1B | c.264C>T p.F88= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as COSV100770772; called by muse, mutect2, varscan2
- SLC22A11 | c.177G>A p.A59= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as rs1178192361, COSV100102525; called by muse, mutect2, varscan2
- SYTL3 | c.459G>A p.V153= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV99792295; called by muse, mutect2
- TNRC6C | c.2961G>T p.L987= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV100050410; called by muse, mutect2, varscan2
- TRBJ2-1 | c.24C>T p.F8= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs782655105; called by muse, mutect2, varscan2
- USH2A | c.3265T>C p.L1089= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as COSV100239165, COSV56405365; called by muse, mutect2, varscan2
- USP13 | c.2454C>T p.S818= | Silent (SNP) | VAF 15/104 reads (14%) | catalogued as COSV99831522; called by muse, mutect2, varscan2
- VSIG4 | c.612C>T p.A204= | Silent (SNP) | VAF 40/119 reads (34%) | catalogued as rs369638381, COSV101038081; called by muse, mutect2, varscan2
- ZBTB37 | c.642C>T p.I214= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as rs372954076, COSV100774616; called by muse, mutect2, varscan2
- ZKSCAN5 | c.867C>T p.S289= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs369038270, COSV100460312; called by muse, mutect2, varscan2
- ZSWIM1 | c.972C>T p.S324= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV99666793; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849233 C>T | 5'Flank (SNP) | VAF 10/53 reads (19%) | called by muse, mutect2, varscan2
- RPS2 | c.710-73T>A | Intron (SNP) | VAF 19/53 reads (36%) | catalogued as COSV99238888; called by muse, mutect2, varscan2
